Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LB, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LB-01A (Primary Tumor).

Procedure: adrenalectomy, and lung wedge resection

Gross description: 8 x 4.5 x 4cm, 44.4g, tumor 5.5 x 5 x 4.5cm

Diagnosis: adrenocortical carcinoma, 8 per 20 hpf, van Slooten index=25.8, Hough index=3.97

Reference Pathology:

Diagnosis: adrenocortical carcinoma infiltrating vena cava, and lung specimen bronchoalveolar carcinoma, KI67 3%

Weiss score: 4

Hough score: 2.44

Van Slooten score: 12.3

ICD-O-3
Carcinoma, adrenal
cortical 8370/3
Site: Adrenal Gland
Cortex C74.0
JLD 2/6/13

HPVAA Discrepancy		

Source: NCI Genomic Data Commons file 763dab00-1d64-42bf-a827-b6239a7956ea (TCGA-OR-A5LB.09038444-9BE4-443C-8FEC-07903972F305.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).